Somatic mutation profile of tumor specimen 0DHY4J from CCDI case PBBUXB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 16.2 years (5,899 days).
Specimen 0DHY4J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96df62bc-89ad-4d89-b6ed-4ed309b065fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHY2T (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56936bf1-0e9f-4510-a14e-86782285ce62

The open-access MAF lists 92 somatic variants for this specimen: 53 protein-altering or splice-affecting, 21 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 21, Intron 7, 5'UTR 6, 3'UTR 5, Nonsense Mutation 3, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 76/532 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, varscan2
- C1orf198 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as COSV64174798; called by muse, mutect2, varscan2
- CARD9 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 80/944 reads (8%) | catalogued as COSV59997108; called by muse, mutect2
- CHST7 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 84/298 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99332990; called by muse, varscan2
- EML5 | c.3521C>T p.S1174L | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV61351052; called by muse, mutect2, varscan2
- KLF5 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs1319210726; called by muse, mutect2, varscan2
- MMP9 | c.1259A>G p.Y420C | Missense Mutation (SNP) | VAF 69/840 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1347107674; called by muse, mutect2
- MSH2 | c.136C>T p.H46Y | Missense Mutation (SNP) | VAF 165/468 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs1553348821; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIF3L1 | c.1129G>A p.V377I (on ENST00000409020 / NM_001369444.1; = p.V350I on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as rs558074352; called by muse, mutect2, varscan2
- NOS1AP | c.735G>C p.K245N | Missense Mutation (SNP) | VAF 77/530 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV100722705, COSV62638033; called by muse, mutect2, varscan2
- OTOGL | c.2416G>T p.G806C (on ENST00000547103; = p.G797C on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/437 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72006767; called by muse, mutect2, varscan2
- PBOV1 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 81/536 reads (15%) | catalogued as rs373323732, COSV52449710; called by muse, mutect2, varscan2
- PCDHA2 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs782183971, COSV65366475; called by muse, varscan2
- PCDHB4 | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1240542538; called by muse, varscan2
- PREX2 | c.1272G>T p.E424D | Missense Mutation (SNP) | VAF 62/604 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV99908190; called by muse, mutect2, varscan2
- SCN11A | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 85/491 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs200995619; called by muse, varscan2
- ZNF469 | c.4804G>A p.V1602I (on ENST00000437464; = p.V1630I on NM_001367624.2) | Missense Mutation (SNP) | VAF 118/238 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.157); catalogued as rs749642726, COSV101458733; called by muse, varscan2
- ACTG2 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 88/447 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- APOOL | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 93/306 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASPM | c.4091G>C p.R1364T | Missense Mutation (SNP) | VAF 43/430 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BIRC6 | c.7514A>G p.K2505R | Missense Mutation (SNP) | VAF 99/619 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- CD5L | c.389C>A p.S130Y | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, varscan2
- CDCA5 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 57/448 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ERBB4 | c.1235C>T p.T412I | Missense Mutation (SNP) | VAF 32/274 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM122A | c.337A>G p.I113V | Missense Mutation (SNP) | VAF 138/720 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GAS1 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 43/379 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GPD2 | c.1715G>C p.R572T | Missense Mutation (SNP) | VAF 89/375 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HPSE2 | c.1712T>C p.I571T | Missense Mutation (SNP) | VAF 71/424 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- INO80C | c.228del p.A77Lfs*21 | Frame Shift Del (DEL) | VAF 71/448 reads (16%) | called by mutect2, varscan2
- KCNA2 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 74/650 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- KCNJ14 | c.479C>A p.P160Q | Missense Mutation (SNP) | VAF 62/748 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2
- KDM5A | c.4355G>C p.G1452A | Missense Mutation (SNP) | VAF 66/350 reads (19%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.995); called by muse, varscan2
- MDFI | c.199C>G p.P67A | Missense Mutation (SNP) | VAF 92/680 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MMP13 | c.526T>C p.Y176H | Missense Mutation (SNP) | VAF 78/465 reads (17%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MN1 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 80/293 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- NR1H2 | c.429G>C p.Q143H | Missense Mutation (SNP) | VAF 103/1046 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2
- OR5AC2 | c.11C>A p.S4* | Nonsense Mutation (SNP) | VAF 32/179 reads (18%) | called by muse, mutect2, varscan2
- OS9 | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 79/569 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PARP14 | c.1689G>C p.K563N | Missense Mutation (SNP) | VAF 96/609 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLA2R1 | c.4194C>G p.I1398M | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRDM13 | c.1288C>A p.P430T | Missense Mutation (SNP) | VAF 65/365 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PRR36 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 34/428 reads (8%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2
- RAB3GAP2 | c.1693A>G p.K565E | Missense Mutation (SNP) | VAF 128/454 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, varscan2
- RIMBP2 | c.671T>G p.V224G | Missense Mutation (SNP) | VAF 157/562 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RLIM | c.1286C>T p.T429I | Missense Mutation (SNP) | VAF 51/317 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SDF2L1 | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 90/416 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SEC24B | c.1694C>G p.T565R | Missense Mutation (SNP) | VAF 76/297 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SIPA1L1 | c.3898G>A p.D1300N | Missense Mutation (SNP) | VAF 79/551 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SPTA1 | c.921G>C p.K307N | Missense Mutation (SNP) | VAF 76/510 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, varscan2
- SPTBN5 | c.4711G>T p.A1571S | Missense Mutation (SNP) | VAF 90/354 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.331); called by muse, varscan2
- XIRP1 | c.5213C>A p.A1738D | Missense Mutation (SNP) | VAF 55/515 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ZDHHC2 | c.716A>C p.N239T | Missense Mutation (SNP) | VAF 74/744 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF619 | c.81C>A p.V27= | Splice Region (SNP) | VAF 83/729 reads (11%) | called by muse, mutect2, varscan2
- ANO4 | c.846G>T p.L282= (on ENST00000392977 / NM_001286615.2; = p.L247= on NM_178826.4) | Silent (SNP) | VAF 32/250 reads (13%) | called by muse, mutect2, varscan2
- CHAF1A | c.2607G>A p.L869= | Silent (SNP) | VAF 73/688 reads (11%) | called by muse, mutect2, varscan2
- DENND11 | c.345C>A p.S115= | Silent (SNP) | VAF 84/432 reads (19%) | called by mutect2, varscan2
- EVPL | c.1857C>T p.D619= | Silent (SNP) | VAF 178/546 reads (33%) | catalogued as rs1273995039; called by muse, mutect2, varscan2
- GLG1 | c.3183C>T p.I1061= | Silent (SNP) | VAF 60/214 reads (28%) | catalogued as COSV99215514; called by muse, mutect2, varscan2
- HTATSF1 | c.1575C>G p.L525= | Silent (SNP) | VAF 78/364 reads (21%) | called by muse, varscan2
- KLRG2 | c.579G>T p.T193= | Silent (SNP) | VAF 54/217 reads (25%) | catalogued as rs1267267963; called by muse, mutect2, varscan2
- LHX5 | c.1089C>A p.P363= | Silent (SNP) | VAF 61/381 reads (16%) | called by muse, mutect2, varscan2
- MEGF9 | c.1767G>A p.G589= | Silent (SNP) | VAF 60/626 reads (10%) | called by muse, mutect2
- OR4K14 | c.141C>T p.V47= | Silent (SNP) | VAF 37/262 reads (14%) | catalogued as rs150156420, COSV100520426; called by muse, mutect2, varscan2
- OR4X2 | c.150C>T p.P50= | Silent (SNP) | VAF 33/240 reads (14%) | catalogued as COSV56583427; called by muse, mutect2, varscan2
- PXMP4 | c.498G>C p.L166= | Silent (SNP) | VAF 54/489 reads (11%) | called by muse, mutect2, varscan2
- SGK1 | c.264G>T p.S88= | Silent (SNP) | VAF 188/536 reads (35%) | catalogued as COSV52809064; called by mutect2, varscan2
- SIK3 | c.1707C>T p.V569= (on ENST00000445177 / NM_001366686.2; = p.V575= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 84/458 reads (18%) | called by muse, mutect2, varscan2
- SPATA4 | c.414T>C p.A138= | Silent (SNP) | VAF 88/276 reads (32%) | called by muse, mutect2, varscan2
- TELO2 | c.957G>T p.L319= | Silent (SNP) | VAF 48/257 reads (19%) | catalogued as COSV99248659; called by muse, mutect2, varscan2
- TRHDE | c.2460G>A p.L820= | Silent (SNP) | VAF 78/443 reads (18%) | called by muse, mutect2, varscan2
- USP51 | c.345C>T p.R115= | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as rs778896426; called by mutect2, varscan2
- VSIG8 | c.1122G>T p.A374= | Silent (SNP) | VAF 42/208 reads (20%) | catalogued as rs985781493; called by muse, mutect2, varscan2
- ZNF175 | c.1662C>T p.T554= | Silent (SNP) | VAF 41/628 reads (7%) | catalogued as rs755644498; called by muse, mutect2
- ZNF423 | c.3747C>G p.A1249= (on ENST00000563137 / NM_001379286.1; = p.A1241= on NM_015069.4) | Silent (SNP) | VAF 82/294 reads (28%) | catalogued as COSV52188699; called by muse, varscan2
- ALG10 | c.-23G>C | 5'UTR (SNP) | VAF 50/365 reads (14%) | called by muse, mutect2, varscan2
- C1orf131 | c.-17G>T | 5'UTR (SNP) | VAF 30/196 reads (15%) | catalogued as rs1396400371, COSV100010010; called by muse, mutect2, varscan2
- C2orf88 | c.*96G>A | 3'UTR (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2, varscan2
- CNN1 | c.*88del | 3'UTR (DEL) | VAF 13/104 reads (13%) | catalogued as COSV99370654; called by mutect2, varscan2
- DKK4 | c.-51G>A | 5'UTR (SNP) | VAF 10/83 reads (12%) | catalogued as rs770430997; called by mutect2, varscan2
- FGF11 | c.-48C>A | 5'UTR (SNP) | VAF 23/159 reads (14%) | called by muse, varscan2
- FOXI2 | c.-77T>G | 5'UTR (SNP) | VAF 4/44 reads (9%) | catalogued as rs1046322320; called by muse, varscan2
- GPD1L | c.*46A>G | 3'UTR (SNP) | VAF 47/259 reads (18%) | catalogued as rs769996606; called by muse, mutect2, varscan2
- KCNT1 | c.3488-30G>T | Intron (SNP) | VAF 21/161 reads (13%) | catalogued as COSV99705401; called by muse, varscan2
- KLHL26 | c.84-4491C>T | Intron (SNP) | VAF 133/372 reads (36%) | catalogued as rs1023819451; called by muse, mutect2, varscan2
- LSM1 | c.*10C>G | 3'UTR (SNP) | VAF 54/421 reads (13%) | called by muse, varscan2
- MAK16 | c.240+95G>A | Intron (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- NEPRO | c.473+76G>C | Intron (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- PABPC4 | c.1405+118G>T | Intron (SNP) | VAF 24/99 reads (24%) | called by muse, mutect2, varscan2
- SULT1C2 | c.*41C>A | 3'UTR (SNP) | VAF 20/112 reads (18%) | catalogued as rs750959639; called by muse, mutect2, varscan2
- TAF9 | c.-110-47A>G | Intron (SNP) | VAF 25/191 reads (13%) | catalogued as rs781664484; called by muse, mutect2, varscan2
- TUBGCP3 | c.1168+239C>A | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- ZNF518B | c.-37T>C | 5'UTR (SNP) | VAF 28/118 reads (24%) | catalogued as rs1378252631; called by mutect2, varscan2
